Somatic mutation profile of tumor specimen 0DQHAY from CCDI case PBCBBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.9 years (4,694 days).
Specimen 0DQHAY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4f96771-10ea-4491-83a2-7ad37201c38c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3cb9a94-fd7d-41cd-b33c-effbf0faa5eb

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNKSR3 | c.507+2T>A p.X169_splice | Splice Site (SNP) | VAF 12/340 reads (4%) | catalogued as COSV72161843; called by muse, mutect2
- OR10J4 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.626); catalogued as rs183747708; called by muse, mutect2, varscan2
- SETD2 | c.4814A>G p.Y1605C | Missense Mutation (SNP) | VAF 28/586 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57436541; called by muse, mutect2
- D2HGDH | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- KRI1 | c.94+28G>C | Intron (SNP) | VAF 6/55 reads (11%) | called by muse, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 2/19 reads (11%) | catalogued as COSV55814242; called by muse, mutect2
